Somatic mutation profile of tumor specimen TARGET-20-PATDYY-09A (aliquot TARGET-20-PATDYY-09A-01D) from TARGET case TARGET-20-PATDYY, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,319 days).
Specimen TARGET-20-PATDYY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bda01903-1d6b-4071-bb97-16cbae263fb1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATDYY-14A (Bone Marrow Normal), aliquot TARGET-20-PATDYY-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c735189-a0ad-47df-9d0b-a245e9a9fbff

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.7738+1G>A p.X2580_splice (on ENST00000358273 / NM_001042492.3; = p.X2559_splice on NM_000267.3) | Splice Site (SNP) | VAF 19/24 reads (79%) | catalogued as CS072266; called by muse, mutect2, varscan2
- PHF6 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 23/26 reads (88%) | catalogued as COSV59699190; called by muse, mutect2, varscan2
- CARD11 | c.1795T>G p.L599V | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
